CCDI case PBCVTW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3a50dae6-bcac-4448-ab9e-7873088186f1

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1KOA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1KOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
